Somatic mutation profile of tumor specimen TCGA-FY-A3NN-01A (aliquot TCGA-FY-A3NN-01A-11D-A21A-08) from TCGA case TCGA-FY-A3NN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 48.2 years (17,613 days).
Specimen TCGA-FY-A3NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e4b596e-3336-4c3a-89ce-6f3c5b4f0f91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3NN-10A (Blood Derived Normal), aliquot TCGA-FY-A3NN-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5771410a-d830-4255-81f7-cb7408be89d7

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL22A1 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs921759426, COSV57352645; called by muse, mutect2
- ITGAM | c.2516G>A p.R839H (on ENST00000648685 / NM_001145808.2; = p.R838H on NM_000632.4) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1475357620, COSV54938709; called by muse, mutect2, varscan2
- TTC21B | c.2174T>C p.F725S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV54633415; called by muse, mutect2, varscan2
- ZNF623 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193521283, COSV71697307; called by muse, mutect2, varscan2
- MICOS10 | c.84A>T p.G28= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV59554683; called by muse, mutect2, varscan2
